Surgical pathology report (de-identified scan), TCGA case TCGA-YL-A9WY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site PROCURE Biobank, specimen TCGA-YL-A9WY-01A (Primary Tumor).

[page 1 of 2]
PROSTATE AND PELVIC/OBTURATOR LYMPH NODES; RADICAL PROSTATECTOMY:

TUMOR PROCUREMENT:

HISTOLOGIC TYPE

ACINAR ADENOCARCINOMA

HISTOLOGIC GRADE (PRIMARY PATTERN+SECONDARY PATTERN = GLEASON SCORE):

5 + 4 = 9

TERTIARY PATTERN NOT PRESENT

PERCENTAGE OF DIFFERENT GLEASON PATTERNS

1: ___%

2: ___%

3: ___%

4: ___5%

5: ___95%

TUMOR LOCATION

APEX

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

EXTRA-PROSTATIC EXTENSION

PRESENT

NON-FOCAL

SITE OF EXTRA-PROSTATIC EXTENSION

APEX

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

SEMINAL VESICAL INVASION

PRESENT

BOTH

SURGICAL MARGINS

INVOLVED BY INVASIVE CARCINOMA

APEX

MID

BASE

ANTERIOR

RIGHT

LEFT

POSTERIOR

RIGHT

LEFT

NATURE OF POSITIVE MARGINS

INDETERMINATE

EXTENT OF POSITIVE MARGINS

MULTIFOCAL

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

Q4 5/19/14

[page 2 of 2]
MILLIMETRIC EXTENT OF POSITIVE MARGINS: 15 MM
GLEASON GRADE OF CARCINOMA PRESENT AT THE POSITIVE MARGINS
5 + 5 = 10
LYMPHOVASCULAR INVASION
PRESENT
PERINEURAL INVASION
NOT REPORTED
TUMOR VOLUME
PROPORTION OF PROSTATE INVOLVED BY CARCINOMA: 70%
TREATMENT EFFECT ON CARCINOMA
NOT APPLICABLE
LYMPH NODES
RIGHT PELVIC OBTURATOR
NUMBER OF NODES IDENTIFIED: 10
NUMBER OF NODES INVOLVED BY METASTASIS: 5
LEFT PELVIC OBTURATOR
NUMBER OF NODES IDENTIFIED: 9
NUMBER OF NODES INVOLVED BY METASTASIS: 6
DIAMETER OF LARGEST LYMPH NODE METASTASIS: NOT REPORTED
ADDITIONAL PATHOLOGIC FINDINGS
NONE REPORTED
PATHOLOGICAL STAGING
pT3b
pN1
pMX

Source: NCI Genomic Data Commons file 7e22150f-bd5a-46b8-817f-9344f96ab5e7 (TCGA-YL-A9WY.50396173-9B31-42A1-81BC-9D2B5905E54A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).